Somatic mutation profile of tumor specimen TCGA-CZ-5451-01A (aliquot TCGA-CZ-5451-01A-01D-1501-10) from TCGA case TCGA-CZ-5451, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 74.8 years (27,312 days).
Specimen TCGA-CZ-5451-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 624065c5-8fb0-4730-973c-3f5c3226dae9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5451-11A (Solid Tissue Normal), aliquot TCGA-CZ-5451-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dea8d464-c6fa-4a76-b22d-746b40693278

The open-access MAF lists 87 somatic variants for this specimen: 70 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 15, Frame Shift Del 9, Nonsense Mutation 7, Frame Shift Ins 2, 3'UTR 1, Splice Site 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC12 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146005796; called by muse, mutect2, varscan2
- ADAR | c.431T>A p.L144* | Nonsense Mutation (SNP) | VAF 46/148 reads (31%) | catalogued as COSV52714128; called by muse, mutect2, varscan2
- AGTR1 | c.674C>G p.A225G | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV62557822; called by muse, mutect2, varscan2
- ANKLE2 | c.691A>T p.M231L | Missense Mutation (SNP) | VAF 176/594 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV61708916; called by muse, mutect2, varscan2
- ATM | c.7480A>T p.N2494Y | Missense Mutation (SNP) | VAF 146/464 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53737785; called by muse, mutect2, varscan2
- ATM | c.7917del p.T2640Lfs*6 | Frame Shift Del (DEL) | VAF 100/338 reads (30%) | catalogued as COSV53737798; called by mutect2, pindel, varscan2
- BIRC6 | c.5953A>T p.N1985Y | Missense Mutation (SNP) | VAF 89/280 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70197962; called by muse, mutect2, varscan2
- CADPS | c.3853C>T p.Q1285* | Nonsense Mutation (SNP) | VAF 24/336 reads (7%) | catalogued as COSV51875117; called by muse, mutect2
- CDKN2C | c.116G>C p.R39T | Missense Mutation (SNP) | VAF 74/240 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52954625, COSV52955721; called by muse, mutect2
- CENPW | c.241-2A>G p.X81_splice | Splice Site (SNP) | VAF 205/654 reads (31%) | catalogued as COSV64176878; called by muse, mutect2, varscan2
- CERS3 | c.742G>C p.A248P | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52567155; called by muse, mutect2, varscan2
- CPAMD8 | c.812A>G p.Y271C (on ENST00000651564; = p.Y224C on NM_015692.5) | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs371807162, COSV52233224; called by muse, mutect2, varscan2
- CPSF7 | c.877C>A p.P293T (on ENST00000394888 / NM_001136040.4; = p.P336T on NM_024811.4) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61210772; called by muse, mutect2, varscan2
- CYP26B1 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV50011465; called by muse, varscan2
- DHX30 | c.1115T>G p.I372S (on ENST00000445061 / NM_138615.3; = p.I333S on NM_014966.3) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV53136825; called by muse, mutect2, varscan2
- DOCK4 | c.5084C>A p.S1695* | Nonsense Mutation (SNP) | VAF 46/120 reads (38%) | catalogued as COSV70235604; called by muse, mutect2, varscan2
- DYNC1H1 | c.907A>G p.I303V | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.054); catalogued as COSV64136071; called by muse, mutect2, varscan2
- ESCO1 | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 128/492 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52519226; called by muse, mutect2, varscan2
- F2 | c.755A>G p.N252S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV61315330; called by muse, mutect2, varscan2
- FAM151A | c.809T>G p.L270R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV56363693; called by muse, mutect2
- GCC1 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 58/148 reads (39%) | catalogued as COSV50000758; called by muse, mutect2, varscan2
- GCKR | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as rs556404401, COSV53021026; called by muse, mutect2, varscan2
- IL27RA | c.1058T>C p.V353A | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54600174; called by muse, mutect2
- ITCH | c.643A>C p.R215= (on ENST00000262650 / NM_001257137.3; = p.R174= on NM_031483.7 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 183/604 reads (30%) | catalogued as COSV52931096, COSV99392397; called by muse, mutect2, varscan2
- KIF1B | c.2986G>A p.V996I (on ENST00000377086 / NM_001365952.1; = p.V950I on NM_015074.3) | Missense Mutation (SNP) | VAF 133/399 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as rs145596547; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF5C | c.2008A>G p.K670E | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs1387953609, COSV68480708; called by muse, mutect2, varscan2
- KNTC1 | c.669+1del | Frame Shift Del (DEL) | VAF 233/932 reads (25%) | catalogued as COSV61079451; called by mutect2, pindel, varscan2
- LAMA4 | c.4609C>A p.H1537N (on ENST00000230538 / NM_001105206.3; = p.H1530N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/422 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV57895285, COSV57900806; called by muse, mutect2, varscan2
- MGAT4A | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 140/436 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV53846514; called by muse, mutect2, varscan2
- ONECUT2 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs769761027, COSV72152960; called by muse, mutect2, varscan2
- OR52J3 | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 190/670 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.099); catalogued as rs1458728124, COSV66746505, COSV66746579; called by muse, mutect2, varscan2
- OR6C4 | c.498C>G p.F166L | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101263143, COSV67792839, COSV67792888; called by muse, mutect2, varscan2
- OR6C68 | c.811G>C p.G271R | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.962); catalogued as COSV65562858, COSV65563076; called by muse, mutect2
- PCSK2 | c.767G>T p.S256I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52730423; called by muse, mutect2, varscan2
- PDE4B | c.910C>A p.L304I | Missense Mutation (SNP) | VAF 135/391 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV58473684; called by muse, mutect2, varscan2
- PDGFD | c.962G>T p.G321V | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); catalogued as COSV56374459; called by muse, mutect2, varscan2
- PDSS2 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64647417; called by muse, mutect2, varscan2
- PREX2 | c.2459G>C p.G820A | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55763290; called by muse, mutect2, varscan2
- PTPRC | c.1486A>T p.T496S | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.124); catalogued as COSV61409584; called by muse, mutect2
- PUM2 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 33/730 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.99); catalogued as COSV57579653; called by muse, mutect2
- PWP1 | c.236G>A p.G79D | Missense Mutation (SNP) | VAF 100/284 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV69832631; called by muse, mutect2, varscan2
- PYGM | c.2461T>C p.Y821H | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51215854; called by muse, mutect2, varscan2
- RARA | c.628A>G p.T210A | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.598); catalogued as COSV54191514; called by muse, mutect2, varscan2
- RASGEF1C | c.835A>C p.I279L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV63179728; called by muse, mutect2, varscan2
- RNF139 | c.770T>G p.L257* | Nonsense Mutation (SNP) | VAF 102/342 reads (30%) | catalogued as COSV52678899; called by muse, mutect2, varscan2
- ROCK1 | c.3235C>T p.Q1079* | Nonsense Mutation (SNP) | VAF 156/519 reads (30%) | catalogued as COSV67695482; called by muse, mutect2, varscan2
- SCARB2 | c.437G>T p.W146L | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV53668443; called by muse, mutect2, varscan2
- SF3A3 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as COSV65955748; called by muse, mutect2, varscan2
- SF3A3 | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1422495676, COSV65955751; called by muse, mutect2, varscan2
- SH2B2 | c.983T>G p.I328S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV60826102; called by muse, mutect2, varscan2
- SLC47A2 | c.79T>C p.F27L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV57627492; called by muse, mutect2, varscan2
- SLC5A10 | c.653T>C p.I218T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV58757252; called by muse, mutect2, varscan2
- SLC7A2 | c.1021G>A p.V341I (on ENST00000494857 / NM_001370338.1; = p.V381I on NM_003046.6) | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs200994837, COSV50250700; called by muse, mutect2
- SRGAP3 | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1162778458, COSV64532264; called by muse, mutect2
- THSD7A | c.3988G>C p.D1330H | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV69855621; called by muse, mutect2, varscan2
- TRARG1 | c.464C>G p.T155S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs1454623153, COSV61562690; called by muse, mutect2, varscan2
- USP24 | c.1799A>C p.E600A | Missense Mutation (SNP) | VAF 126/415 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV53765842; called by muse, mutect2, varscan2
- WFIKKN2 | c.277T>A p.Y93N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV60958384; called by muse, mutect2, varscan2
- ZNF675 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV63095702; called by muse, mutect2
- ZSCAN26 | c.1415A>C p.H472P (on ENST00000623276 / NM_001111039.2; = p.H338P on NM_152736.5) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52552579; called by muse, mutect2, varscan2
- CNOT1 | c.6971_6977del p.I2324Tfs*4 | Frame Shift Del (DEL) | VAF 90/359 reads (25%) | called by mutect2, pindel, varscan2
- DHDH | c.346_347insA p.R116Qfs*90 | Frame Shift Ins (INS) | VAF 7/14 reads (50%) | called by mutect2*, varscan2
- FOCAD | c.5135_5136insG p.P1713Tfs*24 | Frame Shift Ins (INS) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- GRIN2A | c.2539_2540del p.F847Lfs*30 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel*, varscan2
- MYO1C | c.1003del p.L335Sfs*4 (on ENST00000648651 / NM_001080779.2; = p.L300Sfs*4 on NM_033375.5) | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | called by mutect2, pindel, varscan2
- NHLRC2 | c.645del p.D216Ifs*14 | Frame Shift Del (DEL) | VAF 39/150 reads (26%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1988del p.N663Mfs*7 | Frame Shift Del (DEL) | VAF 55/139 reads (40%) | called by mutect2, pindel, varscan2
- SCAP | c.1659_1677del p.L553Ffs*57 | Frame Shift Del (DEL) | VAF 13/25 reads (52%) | called by mutect2, pindel, varscan2
- SERPINB8 | c.539del p.T180Kfs*17 | Frame Shift Del (DEL) | VAF 82/283 reads (29%) | called by mutect2, pindel, varscan2
- TRAC | c.314A>C p.E105A | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATP8B4 | c.2787G>A p.V929= | Silent (SNP) | VAF 62/206 reads (30%) | catalogued as COSV52713385; called by muse, mutect2, varscan2
- CADPS | c.3852T>C p.Y1284= | Silent (SNP) | VAF 24/332 reads (7%) | catalogued as COSV51875132; called by muse, mutect2
- DCAF17 | c.180C>G p.A60= | Silent (SNP) | VAF 153/568 reads (27%) | catalogued as COSV64544876; called by muse, mutect2, varscan2
- DNAJC10 | c.1527A>G p.T509= | Silent (SNP) | VAF 120/460 reads (26%) | catalogued as rs747493044, COSV51136883; called by muse, mutect2
- FBXO34 | c.531T>G p.P177= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV58254151; called by muse, mutect2
- LAMA1 | c.1257C>T p.H419= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as COSV67535183; called by muse, mutect2, varscan2
- LAMA4 | c.4608T>A p.G1536= (on ENST00000230538 / NM_001105206.3; = p.G1529= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 110/420 reads (26%) | catalogued as COSV57895292; called by muse, mutect2, varscan2
- LRRC8A | c.6T>A p.I2= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV52185221; called by muse, mutect2, varscan2
- MRPS33 | c.204T>G p.L68= | Silent (SNP) | VAF 157/462 reads (34%) | catalogued as COSV61341189; called by muse, mutect2, varscan2
- PNN | c.150T>C p.P50= | Silent (SNP) | VAF 203/656 reads (31%) | catalogued as COSV53766007; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2328T>C p.V776= | Silent (SNP) | VAF 122/393 reads (31%) | catalogued as COSV62783186; called by muse, mutect2, varscan2
- SHLD2 | c.1674G>C p.L558= | Silent (SNP) | VAF 89/293 reads (30%) | catalogued as COSV53954115; called by muse, mutect2
- SPOCD1 | c.2460C>A p.A820= | Silent (SNP) | VAF 100/309 reads (32%) | catalogued as COSV57095655; called by muse, mutect2, varscan2
- TNFRSF1A | c.681C>A p.L227= | Silent (SNP) | VAF 42/163 reads (26%) | catalogued as COSV50599452; called by muse, mutect2, varscan2
- VASP | c.372T>G p.L124= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV55606466; called by muse, mutect2, varscan2
- C16orf89 | c.-39G>C | 5'UTR (SNP) | VAF 5/7 reads (71%) | catalogued as COSV60123215; called by muse, mutect2, varscan2
- CSF3R | c.*158C>T | 3'UTR (SNP) | VAF 64/181 reads (35%) | catalogued as COSV58965445; called by muse, mutect2, varscan2
